MMRF case MMRF_2465 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6112809d-a4f0-44dc-ab93-b0ed301c2dbc

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.3 years (24,570 days); ISS stage: II; Days to last known disease status: 711 days (1.9 years); Days to last follow up: 711 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 145 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 145 days.
   Treatment given: Therapeutic agents: Doxorubicin; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 138 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 177 days; Days to treatment end: 178 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 180 days; Days to treatment end: 180 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 4): M Protein 4.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.296 mg/dL; Immunoglobulin G 56 g/L; Immunoglobulin A 0.115 g/L; Immunoglobulin M 0.086 g/L; Beta 2 Microglobulin 5.41 µg/mL; Lactate Dehydrogenase 5.57 µkat/L; Hemoglobin 5.02 mmol/L; Leukocytes 2.83 ×10⁹/L; Absolute Neutrophil 2.15 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 35.1 g/L; Total Protein 10 g/dL; C-Reactive Protein 0.68 mg/dL.
- Day 79 (ECOG 2): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.444 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.309 mg/dL; Immunoglobulin G 6.76 g/L; Immunoglobulin A 0.095 g/L; Immunoglobulin M 0.277 g/L; Lactate Dehydrogenase 7.22 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 5.74 ×10⁹/L; Absolute Neutrophil 3.94 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 68.1 µmol/L; Total Protein 6.3 g/dL.
- Day 172: M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.766 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.326 mg/dL; Immunoglobulin G 4.48 g/L; Immunoglobulin A 0.087 g/L; Immunoglobulin M 0.156 g/L; Beta 2 Microglobulin 1.99 µg/mL; Lactate Dehydrogenase 5.97 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 6.27 ×10⁹/L; Absolute Neutrophil 4.23 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Total Protein 6 g/dL.
- Day 260 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.179 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.399 mg/dL; Immunoglobulin G 4.61 g/L; Immunoglobulin A 0.001 g/L; Immunoglobulin M 0.189 g/L; Lactate Dehydrogenase 6.33 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.72 ×10⁹/L; Absolute Neutrophil 2.97 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 87.5 µmol/L; Total Protein 5.6 g/dL.
- Day 368 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.343 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.416 mg/dL; Immunoglobulin G 4.81 g/L; Immunoglobulin A 0.01 g/L; Immunoglobulin M 0.291 g/L; Lactate Dehydrogenase 5.9 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.22 ×10⁹/L; Absolute Neutrophil 3.21 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 117 µmol/L; Calcium 2.35 mmol/L; Total Protein 5.9 g/dL.
- Day 459 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.512 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.499 mg/dL; Immunoglobulin G 5.01 g/L; Immunoglobulin A 0.107 g/L; Immunoglobulin M 0.287 g/L; Lactate Dehydrogenase 8.32 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.48 ×10⁹/L; Absolute Neutrophil 5.05 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 89.3 µmol/L; Calcium 2.38 mmol/L.
- Day 515 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.577 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 6.5 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 1.12 g/L; Lactate Dehydrogenase 5.92 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.65 ×10⁹/L; Absolute Neutrophil 3.71 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 92.8 µmol/L; Calcium 2.35 mmol/L; Total Protein 6.2 g/dL.
- Day 641 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.385 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.783 mg/dL; Immunoglobulin G 5.17 g/L; Immunoglobulin A 0.292 g/L; Immunoglobulin M 0.461 g/L; Lactate Dehydrogenase 5.07 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 91.1 µmol/L; Total Protein 5.9 g/dL; Glucose 4.84 mmol/L.
- Day 711 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 4.91 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.491 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 76 µmol/L; Total Protein 6.1 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day 1: Weight: 58 kg; Height: 154 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2465_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2465_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
